Somatic mutation profile of tumor specimen TCGA-V1-A9OY-01A (aliquot TCGA-V1-A9OY-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 318782fe-3f50-4e90-8545-62b1a7886605.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OY-10A (Blood Derived Normal), aliquot TCGA-V1-A9OY-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f3f3dda-7c0a-439f-9b87-773d16fc7920

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Splice Site 2, Silent 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE2 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs142367407; called by muse, mutect2, varscan2
- CLASP2 | c.4137G>A p.E1379= (on ENST00000359576; = p.E1378= on NM_015097.3 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100222811; called by muse, mutect2
- DCAF5 | c.1871A>G p.D624G | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); catalogued as rs1416556453, COSV100432301; called by muse, mutect2, varscan2
- GMPPB | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777150806, COSV100246477; called by muse, mutect2, varscan2
- GNL3 | c.72+1G>T p.X24_splice | Splice Site (SNP) | VAF 8/43 reads (19%) | catalogued as rs759941039, COSV101187220; called by muse, mutect2, varscan2
- GNL3 | c.72+2T>C p.X24_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101187221; called by muse, mutect2, varscan2
- GPHN | c.1108G>A p.A370T (on ENST00000315266 / NM_001377519.1; = p.A403T on NM_020806.5) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100015618; called by muse, mutect2, varscan2
- HTR1E | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs761396943, COSV59508708; called by muse, mutect2, varscan2
- MAP7D1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV100294289; called by muse, mutect2, varscan2
- NOS2 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs200623027, COSV100569534; called by muse, mutect2, varscan2
- PER2 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV99611539; called by muse, mutect2
- SLC16A3 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs929879809, COSV101125890; called by muse, mutect2, varscan2
- SPEN | c.5150C>T p.A1717V | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs779004613, COSV65358066; called by muse, mutect2, varscan2
- ATRX | c.1792_1802del p.S598Rfs*3 | Frame Shift Del (DEL) | VAF 70/185 reads (38%) | called by mutect2, pindel, varscan2
- L3MBTL3 | c.936C>T p.D312= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs139205810; called by muse, mutect2, varscan2
- MCMBP | c.1749C>T p.N583= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1006170029, COSV100740031; called by muse, mutect2, varscan2
